Somatic mutation profile of cancer-model specimen HCM-CSHL-0383-C18-85A (3D Organoid; aliquot HCM-CSHL-0383-C18-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-CSHL-0383-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,766 days).
Specimen HCM-CSHL-0383-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 000e2b4e-a48f-4754-93f2-7604089ae45a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0383-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0383-C18-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a82684eb-7346-4e12-bead-7b5209a10e9e

The open-access MAF lists 180 somatic variants for this specimen: 99 protein-altering or splice-affecting, 51 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 51, Intron 12, RNA 8, Splice Site 5, 5'UTR 4, Frame Shift Del 4, Nonsense Mutation 3, Splice Region 2, 3'UTR 2, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1639C>T p.R547W (on ENST00000359125 / NM_172107.4; = p.R519W on NM_004518.6) | Missense Mutation (SNP) | VAF 214/587 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs796052650, CM131778, COSV60557310; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 223/363 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 161/162 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- A3GALT2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 244/245 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV57760969; called by muse, mutect2, varscan2
- ANO2 | c.121G>T p.A41S (on ENST00000356134 / NM_001278597.3; = p.A45S on NM_001278596.3) | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs760891155; called by muse, mutect2, varscan2
- BMPER | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs368522901, COSV104397019; ClinVar: uncertain significance; called by muse, mutect2
- C4BPB | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs564412483; called by muse, mutect2, varscan2
- CABIN1 | c.5008-1G>A p.X1670_splice | Splice Site (SNP) | VAF 223/353 reads (63%) | catalogued as COSV99573796; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 26/39 reads (67%) | catalogued as rs747064410; called by mutect2, varscan2
- CHMP1A | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs986506515; called by muse, mutect2, varscan2
- CHTF18 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as rs373526401; called by muse, mutect2, varscan2
- CLOCK | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 320/456 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs371941858; called by muse, mutect2, varscan2
- CRYGA | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 147/479 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1012021158; called by muse, mutect2, varscan2
- DCC | c.3742G>A p.V1248M | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs201242417, COSV101473359, COSV71429727; called by muse, mutect2, varscan2
- DOCK5 | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs1432816032; called by muse, mutect2, varscan2
- DOLK | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748688866, COSV58279938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOX2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 25/819 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV59908101; called by muse, mutect2
- FREM3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390482820; called by muse, mutect2, varscan2
- HLA-DRB1 | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs781648698; called by muse, mutect2, varscan2
- HNRNPH2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1482002230; called by muse, mutect2
- INTS11 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.08); catalogued as rs771049158, COSV60087515; called by muse, mutect2, varscan2
- KIF7 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768030553; called by muse, mutect2, varscan2
- LYPD8 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 200/815 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370124764; called by muse, mutect2, varscan2
- MAPK11 | c.448-6C>T | Splice Region (SNP) | VAF 116/369 reads (31%) | catalogued as rs985435138; called by muse, mutect2, varscan2
- MISP | c.1426A>G p.K476E | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs190920819; called by muse, mutect2, varscan2
- NDRG4 | c.215G>T p.G72V (on ENST00000570248 / NM_001378344.1; = p.G104V on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50751235; called by muse, mutect2, varscan2
- OR10G7 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 122/470 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57866725; called by muse, mutect2, varscan2
- OR1C1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV101376280, COSV68715856; called by muse, mutect2, varscan2
- OVCH1 | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 205/330 reads (62%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs755776403; called by muse, mutect2, varscan2
- PKHD1L1 | c.10829G>T p.G3610V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1445313168; called by muse, mutect2
- PKN1 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as COSV54394951; called by muse, mutect2, varscan2
- SIRPA | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 185/461 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs573686249; called by muse, mutect2, varscan2
- SLC10A2 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 304/468 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs146712120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 49/49 reads (100%) | catalogued as rs879267207; called by muse, mutect2, varscan2
- SRRM2 | c.5231G>A p.R1744Q | Missense Mutation (SNP) | VAF 192/289 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs200616521, COSV57074161; called by muse, mutect2, varscan2
- STRN3 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766739305; called by muse, mutect2, varscan2
- TENM1 | c.2744G>A p.G915E | Missense Mutation (SNP) | VAF 240/873 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64444850; called by muse, mutect2, varscan2
- TLR9 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.3); catalogued as rs746908600, COSV62345572; called by muse, mutect2, varscan2
- TMEM72 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs201585558; called by muse, mutect2
- UGT2B11 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV71423021; called by muse, mutect2
- UGT3A2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.907); catalogued as rs745757904; called by muse, mutect2, varscan2
- USP5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 107/150 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs782574953; called by muse, mutect2, varscan2
- ZNF285 | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759667078; called by muse, mutect2
- ZNF613 | c.809G>A p.R270H (on ENST00000293471 / NM_001031721.4; = p.R234H on NM_024840.4) | Missense Mutation (SNP) | VAF 171/240 reads (71%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.498); catalogued as rs540973466, COSV53272333; called by muse, varscan2
- ZNF654 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs773897741, COSV58806530; called by muse, mutect2, varscan2
- ZSCAN18 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1254138367; called by muse, mutect2, varscan2
- ACSM6 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- ADAMTS13 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 260/565 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANHX | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.687); called by muse, mutect2
- APC | c.3910del p.I1304* | Frame Shift Del (DEL) | VAF 359/493 reads (73%) | called by mutect2, pindel, varscan2
- ASTN1 | c.3505A>T p.S1169C | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BAHD1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- C4BPB | c.231C>A p.R77= | Splice Region (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- CCND1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 110/359 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDH9 | c.523+2T>C p.X175_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- CMTM6 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 137/361 reads (38%) | called by muse, mutect2, varscan2
- COL1A2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 227/852 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.10481T>C p.V3494A | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYB5R1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDA2R | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ELAPOR1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ENPP2 | c.416A>T p.K139I | Missense Mutation (SNP) | VAF 173/372 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ERCC8 | c.639del p.L213Ffs*4 | Frame Shift Del (DEL) | VAF 110/259 reads (42%) | called by mutect2, pindel, varscan2
- FGA | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FGFR1 | c.890G>A p.G297E (on ENST00000447712 / NM_023110.3; = p.G295E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/473 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FMNL3 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GPT | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 267/832 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIN3B | c.1734G>C p.W578C | Missense Mutation (SNP) | VAF 214/626 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HNF1A | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- HNRNPM | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 164/541 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICA1L | c.818A>T p.D273V | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGSF10 | c.3950C>A p.A1317E | Missense Mutation (SNP) | VAF 103/175 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- INSRR | c.2738-1G>C p.X913_splice | Splice Site (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- INSRR | c.2738-2A>C p.X913_splice | Splice Site (SNP) | VAF 97/225 reads (43%) | called by muse, mutect2, varscan2
- KALRN | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KPRP | c.218A>C p.K73T | Missense Mutation (SNP) | VAF 251/513 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LGALS4 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 20/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LTBP4 | c.784G>C p.E262Q (on ENST00000308370 / NM_001042544.1; = p.E225Q on NM_003573.2) | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.143); called by muse, mutect2
- MADCAM1 | c.1114A>G p.R372G | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEL2 | c.3742C>A p.P1248T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- MAPK8IP2 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC4R | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MOGS | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAP1L4 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NCAN | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 141/223 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NID1 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 134/480 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- OR5H14 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 118/385 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PARVG | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PCDHB10 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RASAL2 | c.483+1G>T p.X161_splice | Splice Site (SNP) | VAF 71/283 reads (25%) | called by muse, mutect2, varscan2
- RIF1 | c.5964_5965del p.E1989Dfs*3 | Frame Shift Del (DEL) | VAF 143/271 reads (53%) | called by mutect2, pindel, varscan2
- SHANK1 | c.4874C>A p.T1625K | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMARCC1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMO | c.2198T>C p.V733A | Missense Mutation (SNP) | VAF 306/666 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SORCS2 | c.2339C>A p.P780H | Missense Mutation (SNP) | VAF 136/361 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRRAP | c.1211A>T p.K404M | Missense Mutation (SNP) | VAF 222/811 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TSBP1 | c.859dup p.M287Nfs*8 (on ENST00000617061; = p.M290Nfs*8 on NM_006781.5) | Frame Shift Ins (INS) | VAF 82/235 reads (35%) | called by mutect2, pindel, varscan2
- UNC79 | c.3420C>A p.D1140E (on ENST00000393151 / NM_001346218.2; = p.D963E on NM_020818.5) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADAMTS10 | c.1014C>T p.N338= | Silent (SNP) | VAF 435/680 reads (64%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2733C>A p.P911= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs749294596; called by muse, mutect2, varscan2
- ADGRV1 | c.2838T>C p.T946= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as rs1428739550; called by muse, mutect2, varscan2
- ASB18 | c.807C>T p.H269= | Silent (SNP) | VAF 18/26 reads (69%) | called by muse, varscan2
- CACNA2D2 | c.3150C>T p.T1050= (on ENST00000479441 / NM_001174051.3; = p.T1043= on NM_006030.4) | Silent (SNP) | VAF 138/297 reads (46%) | catalogued as rs780332550; called by muse, varscan2
- CENPF | c.6423A>G p.K2141= | Silent (SNP) | VAF 75/344 reads (22%) | called by muse, mutect2, varscan2
- COL1A2 | c.2322T>A p.A774= | Silent (SNP) | VAF 228/853 reads (27%) | called by muse, mutect2, varscan2
- COL6A1 | c.2853G>A p.T951= | Silent (SNP) | VAF 106/280 reads (38%) | catalogued as rs890068806; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CRCP | c.330G>A p.E110= | Silent (SNP) | VAF 60/322 reads (19%) | called by muse, mutect2, varscan2
- CYP4F8 | c.552G>A p.E184= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as rs374578505; called by muse, mutect2, varscan2
- DCHS2 | c.1215C>T p.D405= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs1220284219; called by muse, mutect2, varscan2
- DOCK4 | c.4878A>C p.V1626= | Silent (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.7215G>A p.G2405= | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as rs1567012071, COSV100794861; ClinVar: likely benign; called by muse, mutect2, varscan2
- ECM1 | c.540C>T p.I180= | Silent (SNP) | VAF 147/702 reads (21%) | called by muse, mutect2, varscan2
- EDA2R | c.699C>T p.S233= | Silent (SNP) | VAF 113/225 reads (50%) | catalogued as COSV99490433; called by muse, mutect2, varscan2
- EME1 | c.354A>G p.P118= | Silent (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- FLG | c.6057C>T p.H2019= | Silent (SNP) | VAF 552/1968 reads (28%) | catalogued as rs758176214, COSV64240888; called by muse, mutect2
- FNIP1 | c.1989T>C p.V663= | Silent (SNP) | VAF 86/190 reads (45%) | catalogued as CD134243; called by muse, mutect2, varscan2
- FPR2 | c.339C>T p.V113= | Silent (SNP) | VAF 141/423 reads (33%) | called by muse, mutect2, varscan2
- GPR137 | c.537C>T p.S179= | Silent (SNP) | VAF 328/1037 reads (32%) | catalogued as rs371290655; called by muse, mutect2, varscan2
- GREB1L | c.3091C>T p.L1031= | Silent (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- HYDIN | c.1953C>A p.P651= | Silent (SNP) | VAF 22/139 reads (16%) | called by mutect2, varscan2
- IGHA1 | c.552C>T p.S184= | Silent (SNP) | VAF 224/419 reads (53%) | catalogued as rs762122332; called by muse, mutect2, varscan2
- IRS1 | c.3132G>A p.P1044= | Silent (SNP) | VAF 115/177 reads (65%) | catalogued as rs773858412, COSV59340641; called by muse, mutect2, varscan2
- KCTD15 | c.792G>A p.E264= | Silent (SNP) | VAF 55/213 reads (26%) | called by muse, mutect2, varscan2
- LRRC37B | c.1998G>T p.L666= | Silent (SNP) | VAF 80/184 reads (43%) | called by muse, varscan2
- MUC4 | c.10209A>T p.T3403= | Silent (SNP) | VAF 265/1013 reads (26%) | called by muse, mutect2, varscan2
- NALCN | c.1263G>A p.A421= | Silent (SNP) | VAF 100/166 reads (60%) | catalogued as rs140469887; called by muse, mutect2, varscan2
- NLRP11 | c.2454C>T p.Y818= | Silent (SNP) | VAF 132/189 reads (70%) | catalogued as rs199475861; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP3 | c.2685G>A p.T895= | Silent (SNP) | VAF 299/658 reads (45%) | catalogued as rs778287953, COSV60223984; called by muse, mutect2, varscan2
- NRXN1 | c.465C>T p.V155= | Silent (SNP) | VAF 279/421 reads (66%) | catalogued as rs531571569, COSV68004656; called by muse, mutect2, varscan2
- OR10G7 | c.468T>A p.A156= | Silent (SNP) | VAF 123/479 reads (26%) | called by muse, mutect2, varscan2
- OR5H14 | c.327C>A p.T109= | Silent (SNP) | VAF 137/271 reads (51%) | called by muse, varscan2
- OR7G2 | c.984G>A p.R328= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV59689172; called by muse, mutect2
- OR8B8 | c.105C>T p.Y35= | Silent (SNP) | VAF 269/389 reads (69%) | catalogued as rs140268238, COSV60144530; called by muse, mutect2, varscan2
- P2RX7 | c.1206C>A p.S402= | Silent (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4668C>T p.C1556= | Silent (SNP) | VAF 145/691 reads (21%) | called by muse, mutect2, varscan2
- PIK3C2B | c.3552C>T p.C1184= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as COSV65811177; called by muse, mutect2, varscan2
- PRLH | c.186C>T p.D62= | Silent (SNP) | VAF 113/262 reads (43%) | called by muse, mutect2, varscan2
- PRND | c.321C>T p.G107= | Silent (SNP) | VAF 438/1173 reads (37%) | called by muse, mutect2, varscan2
- PTPRR | c.462T>C p.N154= | Silent (SNP) | VAF 81/285 reads (28%) | called by muse, mutect2, varscan2
- SLC38A6 | c.1431C>T p.C477= | Silent (SNP) | VAF 87/168 reads (52%) | called by muse, mutect2, varscan2
- SOX8 | c.453C>T p.F151= | Silent (SNP) | VAF 56/304 reads (18%) | catalogued as rs572388048; called by muse, mutect2, varscan2
- SULT1C3 | c.696C>A p.I232= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs1558668606, COSV100227451; called by muse, mutect2, varscan2
- TAS1R3 | c.2130C>T p.D710= | Silent (SNP) | VAF 358/358 reads (100%) | called by muse, mutect2, varscan2
- TLX2 | c.75G>C p.L25= | Silent (SNP) | VAF 20/607 reads (3%) | called by muse, mutect2
- TNRC18 | c.3063C>T p.Y1021= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs965026108; called by muse, mutect2
- TSHZ1 | c.723G>A p.T241= (on ENST00000580243 / NM_001308210.2; = p.T196= on NM_005786.6) | Silent (SNP) | VAF 99/99 reads (100%) | catalogued as rs777460466; called by muse, mutect2, varscan2
- VPS9D1 | c.849G>A p.P283= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs112830886; called by muse, mutect2, varscan2
- VSTM2L | c.189C>T p.S63= | Silent (SNP) | VAF 114/949 reads (12%) | catalogued as rs1314428733, COSV65096376; called by muse, mutect2, varscan2
- ZNF541 | c.1497C>T p.C499= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1244066791; called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793358 G>A | 3'Flank (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- AC134312.1 | n.385_387del | RNA (DEL) | VAF 45/164 reads (27%) | called by pindel, varscan2
- AC136604.1 | n.541G>T | RNA (SNP) | VAF 287/337 reads (85%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840428 G>A | 5'Flank (SNP) | VAF 120/2124 reads (6%) | catalogued as COSV100005280, COSV58335709; called by muse, mutect2
- ARHGEF25 | chr12:57610214 A>T | 5'Flank (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- ART3 | c.847+47G>C | Intron (SNP) | VAF 92/317 reads (29%) | called by muse, mutect2, varscan2
- C7orf66 | n.294C>A | RNA (SNP) | VAF 80/523 reads (15%) | called by muse, mutect2, varscan2
- CHCHD5 | c.-18G>T | 5'UTR (SNP) | VAF 78/383 reads (20%) | called by muse, mutect2, varscan2
- CLUHP11 | n.200A>G | RNA (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- CLUHP11 | n.201G>T | RNA (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- CNNM3 | c.*357C>T | 3'UTR (SNP) | VAF 185/312 reads (59%) | called by muse, mutect2, varscan2
- DAPK1 | c.1626+16A>G | Intron (SNP) | VAF 141/289 reads (49%) | called by muse, mutect2, varscan2
- FKBP6 | c.-145C>T | 5'UTR (SNP) | VAF 124/502 reads (25%) | called by muse, mutect2, varscan2
- FOXO3B | chr17:18662780 del T | 3'Flank (DEL) | VAF 52/106 reads (49%) | called by mutect2, varscan2
- FRMPD2B | n.896C>T | RNA (SNP) | VAF 301/799 reads (38%) | catalogued as rs1182139298; called by muse, mutect2, varscan2
- GP6 | c.*166A>T | 3'UTR (SNP) | VAF 195/642 reads (30%) | called by muse, mutect2, varscan2
- KCNH2 | c.1128+1853G>A | Intron (SNP) | VAF 152/602 reads (25%) | called by muse, mutect2, varscan2
- KLF4 | c.1100-42G>A | Intron (SNP) | VAF 62/112 reads (55%) | catalogued as rs376228612; called by muse, mutect2, varscan2
- LINC02691 | n.1436G>A | RNA (SNP) | VAF 90/195 reads (46%) | catalogued as rs1385989822; called by muse, mutect2, varscan2
- LY9 | c.454+1809C>A | Intron (SNP) | VAF 86/360 reads (24%) | called by muse, mutect2, varscan2
- MEGF8 | c.2737-33G>A | Intron (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- MYO1F | c.232-35C>T | Intron (SNP) | VAF 135/366 reads (37%) | called by muse, mutect2, varscan2
- NOP56 | c.570-23G>A | Intron (SNP) | VAF 149/712 reads (21%) | called by muse, mutect2, varscan2
- SEC14L4 | c.175-100G>A | Intron (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- SLC13A3 | c.-23C>T | 5'UTR (SNP) | VAF 48/381 reads (13%) | called by muse, mutect2, varscan2
- SLC2A10 | c.-40C>G | 5'UTR (SNP) | VAF 187/1354 reads (14%) | catalogued as COSV100826385; called by muse, mutect2, varscan2
- TBXAS1 | c.-79-107C>T | Intron (SNP) | VAF 53/339 reads (16%) | called by muse, mutect2, varscan2
- TMEM183B | n.70C>T | RNA (SNP) | VAF 155/343 reads (45%) | catalogued as rs1438306303; called by muse, mutect2, varscan2
- TSPAN14 | c.133-9C>G | Intron (SNP) | VAF 127/499 reads (25%) | called by muse, mutect2, varscan2
- WSCD2 | c.1346-3437C>T | Intron (SNP) | VAF 244/397 reads (61%) | catalogued as rs920365329; called by muse, mutect2, varscan2
